Somatic mutation profile of tumor specimen ALCH-AFDJ-TTP1-A (aliquot ALCH-AFDJ-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-AFDJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.9 years (28,826 days).
Specimen ALCH-AFDJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e26c2dd6-c1e1-4d69-9122-5b7518c8b181.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFDJ-NB1-A (Blood Derived Normal), aliquot ALCH-AFDJ-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1d83c11-96b8-48ba-9c61-5bddee6beb7f

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Splice Site 2, Frame Shift Del 2, 5'UTR 2, 3'UTR 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 53/1099 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 78/575 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BTBD8 | c.4166G>T p.R1389I (on ENST00000636805 / NM_001376131.1; = p.R876I on NM_015237.4) | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs945455867; called by muse, mutect2
- MS4A14 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 36/811 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1278582491, COSV55733266; called by muse, mutect2
- MYH8 | c.777del p.K260Sfs*7 | Frame Shift Del (DEL) | VAF 154/1042 reads (15%) | catalogued as COSV67969749; called by mutect2, pindel, varscan2
- PIEZO2 | c.3566C>T p.P1189L | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1398574760; called by muse, mutect2
- RC3H2 | c.3160G>A p.D1054N | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV61801776; called by muse, mutect2, varscan2
- SASH3 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs749177330, COSV63556720; called by muse, mutect2, varscan2
- SIK3 | c.1363C>T p.R455C (on ENST00000445177 / NM_001366686.2; = p.R461C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/592 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs189257553, COSV52618877; called by muse, mutect2
- TRAK1 | c.959G>A p.R320Q (on ENST00000327628 / NM_001349247.2; = p.R262Q on NM_014965.5) | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as rs1052288441; called by muse, mutect2
- UNC79 | c.6608G>T p.C2203F (on ENST00000393151 / NM_001346218.2; = p.C2026F on NM_020818.5) | Missense Mutation (SNP) | VAF 72/437 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs928773005; called by muse, varscan2
- ZNF134 | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 64/418 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV101270768; called by muse, mutect2, varscan2
- AFF1 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); called by muse, mutect2
- ATAD3C | c.1090-1G>C p.X364_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- BUB1 | c.376A>T p.I126F | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- CAPRIN1 | c.1293+2dup p.X431_splice | Splice Site (INS) | VAF 54/368 reads (15%) | called by mutect2, pindel, varscan2
- CCDC121 | c.524T>C p.M175T | Missense Mutation (SNP) | VAF 31/676 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- CES2 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYGS | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 104/541 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- DSG4 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 41/825 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2
- EP300 | c.1028T>G p.V343G | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GK | c.185A>G p.H62R | Missense Mutation (SNP) | VAF 152/1081 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- GREM2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- KDM6B | c.3997G>T p.D1333Y | Missense Mutation (SNP) | VAF 72/445 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOGS | c.351C>T p.T117= | Splice Region (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- NCAM2 | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 21/720 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- OSBPL3 | c.2287G>T p.G763C | Missense Mutation (SNP) | VAF 55/353 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- PARD3 | c.2745A>G p.I915M | Missense Mutation (SNP) | VAF 88/972 reads (9%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.503); called by muse, mutect2
- PNPLA7 | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PSIP1 | c.444dup p.R149Efs*12 | Frame Shift Ins (INS) | VAF 74/408 reads (18%) | called by mutect2, pindel, varscan2
- PTPN22 | c.1555G>A p.D519N (on ENST00000359785 / NM_001193431.2; = p.D464N on NM_012411.5) | Missense Mutation (SNP) | VAF 26/983 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.012); called by muse, mutect2
- RETREG2 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- SEPTIN14 | c.936del p.K312Nfs*41 | Frame Shift Del (DEL) | VAF 67/425 reads (16%) | called by mutect2, varscan2
- TRAV38-2DV8 | c.16T>G p.F6V | Missense Mutation (SNP) | VAF 23/378 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- UNC5C | c.426C>A p.C142* | Nonsense Mutation (SNP) | VAF 72/642 reads (11%) | called by mutect2, varscan2
- WDR27 | c.2287G>T p.D763Y | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C5orf51 | c.576A>G p.L192= | Silent (SNP) | VAF 32/665 reads (5%) | called by muse, mutect2
- INO80D | c.2538C>G p.P846= | Silent (SNP) | VAF 32/512 reads (6%) | called by muse, mutect2
- KDR | c.336G>A p.S112= | Silent (SNP) | VAF 141/885 reads (16%) | catalogued as rs1031416918, COSV55771961, COSV99818424; called by muse, mutect2, varscan2
- NOS2 | c.261C>T p.I87= | Silent (SNP) | VAF 15/186 reads (8%) | catalogued as COSV58223506; called by muse, mutect2
- NR0B1 | c.1254G>A p.T418= | Silent (SNP) | VAF 135/830 reads (16%) | catalogued as rs776527316, COSV66764272; called by muse, mutect2, varscan2
- TLDC2 | c.381C>T p.S127= | Silent (SNP) | VAF 15/256 reads (6%) | called by muse, mutect2
- VSTM1 | c.699A>C p.A233= | Silent (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2
- ACADSB | c.43-6777A>G | Intron (SNP) | VAF 7/148 reads (5%) | catalogued as rs1229399665; called by muse, mutect2
- QSOX1 | c.*268C>G | 3'UTR (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- SLC35B4 | c.-1C>T | 5'UTR (SNP) | VAF 48/250 reads (19%) | called by muse, mutect2, varscan2
- TPGS2 | c.-1C>T | 5'UTR (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
